Somatic mutation profile of tumor specimen MP2PRT-PAVNYR-TMP1-A (aliquot MP2PRT-PAVNYR-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVNYR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.8 years (1,024 days).
Specimen MP2PRT-PAVNYR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83fc8367-0a5d-4c6f-b5df-fc0be62c0b10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNYR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNYR-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f6fb86-f555-4504-8f10-6a78c6baa975

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD1 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 26/630 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100517519; called by muse, mutect2
- PTGIS | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 209/560 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs267605985; called by muse, varscan2
- BTBD9 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 56/559 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2
- IGHV4-59 | c.349_350insGGCTTGAGAG p.*117delinsGLER | Silent (INS) | VAF 23/76 reads (30%) | called by pindel, varscan2*
- IGHV4-61 | c.355_356insGGCTTGAGAG p.*119delinsGLER | Silent (INS) | VAF 33/50 reads (66%) | called by pindel, varscan2*
- PEPD | c.885C>T p.N295= | Silent (SNP) | VAF 169/377 reads (45%) | catalogued as rs771953603, COSV54890995; called by muse, mutect2, varscan2
- TBC1D16 | c.801C>T p.A267= | Silent (SNP) | VAF 146/363 reads (40%) | catalogued as rs112925004, COSV60481194; called by muse, mutect2, varscan2
